Somatic mutation profile of tumor specimen MP2PRT-PARXYG-TMP1-A (aliquot MP2PRT-PARXYG-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARXYG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,381 days).
Specimen MP2PRT-PARXYG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 525376d9-2006-41fc-b261-d325fcbb3a2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARXYG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARXYG-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e5a1d6b-27e5-4b8d-bb26-ef14bc219ac8

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Ins 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1153A>C p.T385P (on ENST00000281708 / NM_001349798.2; = p.T305P on NM_018315.5) | Missense Mutation (SNP) | VAF 46/101 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55925981; called by muse, mutect2, varscan2
- KMT2B | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 187/459 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs1454406244; called by muse, mutect2, varscan2
- RBM12 | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 46/918 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); catalogued as rs988746137, COSV58290325; called by muse, mutect2
- ARHGAP22 | c.2041T>C p.F681L | Missense Mutation (SNP) | VAF 232/549 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EP300 | c.5260delinsGCC p.S1754Afs*9 | Frame Shift Ins (INS) | VAF 165/502 reads (33%) | called by pindel, varscan2*
- FREM1 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 48/574 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- H2BC6 | c.183dup p.I62Dfs*74 | Frame Shift Ins (INS) | VAF 254/698 reads (36%) | called by mutect2, pindel, varscan2
- MUC16 | c.33916G>T p.A11306S | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- NR3C1 | c.1828T>A p.W610R | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NUDT11 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 42/1017 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- SSU72P4 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 146/772 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, varscan2
- TNIK | c.1652T>G p.M551R | Missense Mutation (SNP) | VAF 154/385 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF444 | c.399_400insGGCCTCCT p.P134Gfs*5 | Frame Shift Ins (INS) | VAF 118/351 reads (34%) | called by mutect2, pindel, varscan2
- AL592490.1 | c.192G>T p.R64= | Silent (SNP) | VAF 42/741 reads (6%) | called by muse, mutect2
- ANKRD24 | c.2790G>T p.R930= | Silent (SNP) | VAF 56/1154 reads (5%) | catalogued as rs752828083; called by muse, mutect2
- HERC2 | c.7362G>A p.S2454= | Silent (SNP) | VAF 137/564 reads (24%) | catalogued as rs768716342; called by muse, mutect2, varscan2
- IGLV4-69 | c.359A>T p.*120= | Silent (SNP) | VAF 101/248 reads (41%) | called by muse, mutect2, varscan2
- TSKS | c.741G>A p.E247= | Silent (SNP) | VAF 35/1057 reads (3%) | catalogued as COSV55874577; called by muse, mutect2
